Somatic mutation profile of tumor specimen TCGA-DB-A64O-01A (aliquot TCGA-DB-A64O-01A-11D-A29Q-08) from TCGA case TCGA-DB-A64O, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 59.7 years (21,811 days).
Specimen TCGA-DB-A64O-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 47409b85-1293-4813-b10c-ca2e4ce3abfe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DB-A64O-10A (Blood Derived Normal), aliquot TCGA-DB-A64O-10A-01D-A29Q-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/460f1229-d490-47df-a82c-071230edab1d

The open-access MAF lists 18 somatic variants for this specimen: 15 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Frame Shift Del 3, Silent 1, Splice Region 1, 3'UTR 1, RNA 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.1949T>A p.L650* | Nonsense Mutation (SNP) | VAF 40/172 reads (23%) | catalogued as rs1135402826, COSV62197986; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NF1 | c.3739_3742del p.F1247Ifs*18 | Frame Shift Del (DEL) | VAF 57/230 reads (25%) | catalogued as rs1064794276; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- AMOTL1 | c.1208A>G p.H403R | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.067); catalogued as rs370254208; called by muse, mutect2, varscan2
- FANCD2 | c.1106A>G p.E369G | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as rs1559375994, COSV55043348; called by muse, varscan2
- GABRB2 | c.1397G>A p.R466H (on ENST00000274547; = p.R428H on NM_000813.3) | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.013); catalogued as rs772293871, COSV50929966; called by muse, mutect2, varscan2
- HPS6 | c.2172G>T p.E724D | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as COSV54626350; called by muse, mutect2, varscan2
- MUC2 | c.1069G>A p.G357R | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as rs148500799; called by muse, mutect2, varscan2
- MYH2 | c.2378G>A p.R793Q | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.022); catalogued as rs578188627, COSV55443758; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PHF3 | c.4802A>G p.Q1601R | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.058); catalogued as COSV50330090; called by muse, mutect2, varscan2
- SLC9A7 | c.1240G>A p.E414K | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1414753618, COSV60382356; called by muse, mutect2, varscan2
- SPATA31A3 | c.2242G>A p.V748M | Missense Mutation (SNP) | VAF 20/139 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as rs1468994246; called by mutect2, varscan2
- TULP1 | c.828G>A p.A276= | Splice Region (SNP) | VAF 5/13 reads (38%) | catalogued as rs929294496, COSV57693397; called by muse, mutect2
- WFS1 | c.2392G>A p.V798I | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs377712049; called by muse, mutect2, varscan2
- NEGR1 | c.113_114del p.V38Gfs*21 | Frame Shift Del (DEL) | VAF 20/119 reads (17%) | called by pindel, varscan2
- PTPRU | c.1159_1186del p.P387Rfs*5 | Frame Shift Del (DEL) | VAF 10/67 reads (15%) | called by mutect2, pindel
- CPN2 | c.912C>G p.V304= | Silent (SNP) | VAF 19/95 reads (20%) | catalogued as rs374665691, COSV60471189; called by muse, mutect2, varscan2
- ARHGAP42 | c.*3684del | 3'UTR (DEL) | VAF 23/131 reads (18%) | called by mutect2, pindel, varscan2
- SNORD116-4 | n.75G>A | RNA (SNP) | VAF 62/233 reads (27%) | catalogued as rs373230703; called by muse, mutect2, varscan2
